Somatic mutation profile of tumor specimen ALCH-B3FT-TTP1-A (aliquot ALCH-B3FT-TTP1-A-2-0-D-A80C-36) from ALCHEMIST case ALCH-B3FT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.8 years (24,414 days).
Specimen ALCH-B3FT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7264a5e9-d393-4253-b4e1-d0810f013252.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3FT-NB1-A (Blood Derived Normal), aliquot ALCH-B3FT-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c301d8d-6d6e-4c1a-aa3c-eb7df4622e87

The open-access MAF lists 285 somatic variants for this specimen: 201 protein-altering or splice-affecting, 50 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 174, Silent 50, Nonsense Mutation 15, Intron 12, RNA 10, Splice Site 6, 3'UTR 5, 5'UTR 5, Splice Region 3, Translation Start Site 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1255G>T p.G419W | Missense Mutation (SNP) | VAF 46/588 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61684455, COSV61686976, COSV61690433; called by muse, mutect2
- TP53 | c.673-1G>T p.X225_splice | Splice Site (SNP) | VAF 15/250 reads (6%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by muse, mutect2
- A2ML1 | c.428C>G p.T143S | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV55291412; called by muse, mutect2
- ABCC12 | c.2758G>T p.D920Y | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60912946; called by muse, mutect2
- ADAM12 | c.89-1G>T p.X30_splice | Splice Site (SNP) | VAF 16/190 reads (8%) | catalogued as COSV100900271; called by muse, mutect2
- ADAMTS12 | c.2827C>A p.L943M | Missense Mutation (SNP) | VAF 133/497 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.885); catalogued as rs926051279; called by muse, mutect2, varscan2
- ADAMTS16 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs923035798; called by muse, mutect2, varscan2
- AGMO | c.1138G>C p.G380R | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100693819, COSV61113891; called by muse, mutect2
- ANKRD36 | c.3259A>G p.K1087E | Missense Mutation (SNP) | VAF 45/1070 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.066); catalogued as rs773166006; called by muse, mutect2
- AP2B1 | c.1769G>T p.R590L | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV51998010; called by muse, mutect2, varscan2
- APBB1IP | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 22/345 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63076710; called by muse, mutect2
- ARHGAP35 | c.2395A>G p.I799V | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1464086405; called by muse, mutect2
- BBS2 | c.1743A>T p.Q581H | Missense Mutation (SNP) | VAF 56/788 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs368384736; called by muse, mutect2
- BTNL2 | c.1123G>T p.G375* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV66630654; called by muse, mutect2, varscan2
- CCDC22 | c.1244T>C p.I415T | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as rs782575845; called by muse, mutect2
- CDH10 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV52572277, COSV52589543; called by muse, mutect2
- COL11A1 | c.3946G>T p.D1316Y | Missense Mutation (SNP) | VAF 67/934 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1390638679, COSV62185037, COSV62199244; called by muse, mutect2
- COL1A2 | c.2784C>T p.G928= | Splice Region (SNP) | VAF 107/964 reads (11%) | catalogued as COSV51952432, COSV99801432; called by muse, mutect2, varscan2
- CUBN | c.5062G>T p.E1688* | Nonsense Mutation (SNP) | VAF 35/587 reads (6%) | catalogued as COSV64718118; called by muse, mutect2
- DHX57 | c.1927T>C p.Y643H | Missense Mutation (SNP) | VAF 58/484 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1424542681; called by muse, varscan2
- DNAH5 | c.11545G>T p.G3849C | Missense Mutation (SNP) | VAF 200/886 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV54249947, COSV99453171; called by muse, mutect2, varscan2
- ETV5 | c.678C>G p.C226W | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60502312; called by muse, mutect2, varscan2
- FAM135B | c.4144G>A p.A1382T | Missense Mutation (SNP) | VAF 67/639 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99424665; called by muse, mutect2, varscan2
- FAM135B | c.3571A>T p.T1191S | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs766881544; called by muse, mutect2
- FDCSP | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 25/360 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV58765337; called by muse, mutect2
- H2BC10 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 36/610 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.92); catalogued as COSV59953594; called by muse, mutect2
- HECW2 | c.2339G>A p.G780D | Missense Mutation (SNP) | VAF 39/322 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs1246148994; called by muse, mutect2
- IWS1 | c.2334G>T p.Q778H | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99767113; called by muse, mutect2
- KRTAP13-3 | c.242A>G p.Y81C | Missense Mutation (SNP) | VAF 26/307 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs751670222; called by muse, mutect2
- LNPEP | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99183601; called by muse, mutect2
- LTBP4 | c.4706G>A p.R1569H (on ENST00000308370 / NM_001042544.1; = p.R1532H on NM_003573.2) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.354); catalogued as rs897376392; called by muse, mutect2
- MAGEB6 | c.1163C>G p.P388R | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1241312710; called by muse, mutect2
- MAML2 | c.2767G>A p.A923T | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT tolerated (0.97); PolyPhen benign (0.438); catalogued as rs1450706413; called by muse, mutect2
- MMP16 | c.350G>C p.R117P | Missense Mutation (SNP) | VAF 41/498 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV54164309; called by muse, mutect2
- MMP16 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 41/507 reads (8%) | catalogued as COSV54152011, COSV54191186; called by muse, mutect2
- MS4A14 | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV55731502; called by muse, mutect2
- MS4A8 | c.600C>A p.C200* | Nonsense Mutation (SNP) | VAF 29/381 reads (8%) | catalogued as COSV100282335; called by muse, mutect2
- MTF1 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 24/489 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV65990614; called by muse, mutect2
- MUC4 | c.8416G>A p.A2806T | Missense Mutation (SNP) | VAF 61/372 reads (16%) | SIFT tolerated, low confidence (0.55); PolyPhen possibly damaging (0.494); catalogued as rs530066757; called by muse, mutect2, varscan2
- OPHN1 | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as rs1236873845, COSV62783116; called by muse, mutect2
- OR52N2 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57677642; called by muse, mutect2
- OR5B21 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 18/448 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs1232596941; called by muse, mutect2
- OR5L1 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61734762; called by muse, mutect2
- OR6K3 | c.164T>C p.I55T (on ENST00000368146; = p.I39T on NM_001005327.2) | Missense Mutation (SNP) | VAF 25/368 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as rs1235418939; called by muse, mutect2
- ORAI3 | c.228+1G>C p.X76_splice | Splice Site (SNP) | VAF 15/103 reads (15%) | catalogued as rs576699921; called by muse, varscan2
- OTOP3 | c.578G>A p.W193* | Nonsense Mutation (SNP) | VAF 18/132 reads (14%) | catalogued as COSV60914762; called by muse, varscan2
- PCLO | c.13558G>T p.G4520C | Missense Mutation (SNP) | VAF 33/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100433910; called by muse, mutect2
- PCLO | c.11250G>T p.R3750S | Missense Mutation (SNP) | VAF 54/813 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV61657434, COSV61683646; called by muse, mutect2
- PLCL2 | c.1636A>T p.T546S (on ENST00000615277 / NM_001144382.2; = p.T420S on NM_015184.5) | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV101196727; called by muse, mutect2
- PLCZ1 | c.1688C>A p.A563E | Missense Mutation (SNP) | VAF 44/623 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV56851351; called by muse, mutect2
- PRDM9 | c.1145-1G>C p.X382_splice | Splice Site (SNP) | VAF 181/714 reads (25%) | catalogued as COSV57002675; called by muse, mutect2, varscan2
- PRKCI | c.1315C>T p.L439F | Missense Mutation (SNP) | VAF 37/457 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374883456; called by muse, mutect2
- RBM11 | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68747936; called by muse, mutect2, varscan2
- RXFP1 | c.2088G>T p.W696C | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV57057853; called by muse, mutect2
- SCN10A | c.1093A>T p.T365S | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71862228; called by mutect2, varscan2
- SCNN1B | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1206510622; called by muse, mutect2
- SLC15A2 | c.1551G>A p.V517= | Splice Region (SNP) | VAF 15/309 reads (5%) | catalogued as rs1172145405; called by muse, mutect2
- SOX18 | c.1038C>A p.H346Q | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as rs868750846; called by muse, mutect2, varscan2
- STON1 | c.1749G>T p.W583C | Missense Mutation (SNP) | VAF 40/535 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV59134517; called by muse, mutect2
- SWI5 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.2); catalogued as rs1171368219; called by muse, mutect2
- TEX15 | c.2960T>C p.L987S (on ENST00000256246; = p.L1370S on NM_001350162.2) | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56354560; called by muse, mutect2
- TG | c.7777A>G p.I2593V | Missense Mutation (SNP) | VAF 66/627 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs745950808; called by muse, mutect2, varscan2
- TRPA1 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 82/1076 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100085491; called by muse, mutect2
- UQCRHL | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV72331632; called by mutect2, varscan2
- VWDE | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 19/261 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV51721999, COSV51722802; called by muse, mutect2
- ZNF23 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV61841685; called by muse, mutect2
- ZNF630 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs371692087, COSV99332223; called by muse, mutect2
- ZNF674 | c.568C>A p.Q190K | Missense Mutation (SNP) | VAF 34/536 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.213); catalogued as COSV101345054; called by muse, mutect2
- ZP4 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV63911790; called by muse, mutect2, varscan2
- ABCB1 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 46/475 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB11 | c.2392G>T p.V798L | Missense Mutation (SNP) | VAF 21/424 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- ABCF2-H2BE1 | c.1735-1G>A p.X579_splice | Splice Site (SNP) | VAF 23/449 reads (5%) | called by muse, mutect2
- ACAN | c.801G>T p.Q267H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- ACE | c.656G>C p.G219A | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ACSS1 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.334); called by muse, mutect2
- ADAM29 | c.1300G>C p.G434R | Missense Mutation (SNP) | VAF 25/311 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADAT1 | c.775A>C p.T259P | Missense Mutation (SNP) | VAF 24/443 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRG2 | c.2542T>A p.F848I (on ENST00000379869 / NM_001079858.3; = p.F845I on NM_005756.4) | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- ADH7 | c.303A>T p.K101N | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AKAP13 | c.2840T>A p.L947* | Nonsense Mutation (SNP) | VAF 26/382 reads (7%) | called by muse, mutect2
- ANK2 | c.1111G>T p.V371F | Missense Mutation (SNP) | VAF 77/667 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AOX1 | c.2931G>C p.W977C | Missense Mutation (SNP) | VAF 58/669 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ASTN2 | c.1729C>A p.Q577K (on ENST00000313400 / NM_001365069.1; = p.Q526K on NM_014010.5) | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- BCL7A | c.102A>T p.K34N | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BPIFB4 | c.1508C>A p.T503N | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.228); called by muse, mutect2
- C4orf54 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CALM1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.779); called by muse, mutect2
- CCSER1 | c.1540C>G p.L514V | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- CDH22 | c.766G>T p.G256C | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CDKL5 | c.2887C>A p.P963T | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2
- CFAP47 | c.8350G>T p.E2784* | Nonsense Mutation (SNP) | VAF 28/369 reads (8%) | called by muse, mutect2
- CLVS2 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 30/432 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.024); called by muse, mutect2
- COL5A3 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CPA3 | c.680G>T p.W227L | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CSMD1 | c.6619_6621del p.P2207del (on ENST00000520002; = p.P2206del on NM_033225.6) | In Frame Del (DEL) | VAF 13/107 reads (12%) | called by mutect2, pindel, varscan2
- CSMD3 | c.9594G>A p.M3198I (on ENST00000297405 / NM_001363185.1; = p.M3029I on NM_052900.3) | Missense Mutation (SNP) | VAF 45/928 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- CUBN | c.1640G>T p.R547I | Missense Mutation (SNP) | VAF 60/1366 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- DCAF8L1 | c.1466C>A p.P489H | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH5 | c.4885C>A p.Q1629K | Missense Mutation (SNP) | VAF 86/845 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAJC13 | c.5513A>G p.Y1838C | Missense Mutation (SNP) | VAF 78/770 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.428); called by muse, mutect2
- DNTT | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 16/264 reads (6%) | called by muse, mutect2
- EDC4 | c.3086A>G p.Q1029R | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.236); called by muse, mutect2
- EDDM3B | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 27/565 reads (5%) | called by muse, mutect2
- FAAH2 | c.1136A>T p.D379V | Missense Mutation (SNP) | VAF 49/331 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAM124B | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.013); called by muse, mutect2
- FAM160A2 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FANK1 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 59/669 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GON4L | c.5498G>A p.G1833E | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIN2A | c.1634C>T p.S545L | Missense Mutation (SNP) | VAF 40/569 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); called by muse, mutect2
- HADHA | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 43/358 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HDX | c.1105A>G p.R369G | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- HECW2 | c.2341T>A p.S781T | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2
- HERC5 | c.2167G>T p.G723* | Nonsense Mutation (SNP) | VAF 28/362 reads (8%) | called by muse, mutect2
- IGKV1-27 | c.72C>G p.I24M | Missense Mutation (SNP) | VAF 24/721 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2
- IGKV1D-42 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- IGKV3-20 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.602); called by muse, mutect2
- IKBKE | c.1673A>G p.K558R | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2
- IL1R2 | c.1107G>A p.M369I | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- IQCK | c.605A>T p.H202L | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2
- IQGAP2 | c.3646A>T p.I1216F | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2
- KCNJ14 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCNQ1 | c.29C>G p.A10G | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, varscan2
- KRT9 | c.1400C>G p.S467C | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KRTAP4-6 | c.368G>T p.R123M | Missense Mutation (SNP) | VAF 41/530 reads (8%) | SIFT deleterious (0.02); called by muse, mutect2
- LGI1 | c.1603T>C p.F535L | Missense Mutation (SNP) | VAF 20/418 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.649); called by muse, mutect2
- LIN9 | c.1241T>C p.L414P (on ENST00000366808 / NM_001270410.2; = p.L359P on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/276 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LIPA | c.224A>T p.D75V | Missense Mutation (SNP) | VAF 23/574 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- LPIN3 | c.1294C>G p.L432V | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- LYST | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 21/324 reads (6%) | called by muse, mutect2
- MAGEB3 | c.583G>T p.G195W | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEE1 | c.1966G>T p.G656C | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- MAML2 | c.2768C>T p.A923V | Missense Mutation (SNP) | VAF 29/343 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.637); called by muse, mutect2
- MAP3K15 | c.1880C>A p.T627K | Missense Mutation (SNP) | VAF 29/351 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.021); called by muse, mutect2
- MARCHF1 | c.253T>G p.C85G (on ENST00000274056; = p.C68G on NM_017923.4) | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2
- MBD5 | c.3850G>T p.V1284L | Missense Mutation (SNP) | VAF 26/576 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2
- MED23 | c.3068A>T p.K1023I | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEGF10 | c.2927G>A p.C976Y | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MGAT5B | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- MUC16 | c.8575C>A p.L2859I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- NDUFV2 | c.742G>C p.G248R | Missense Mutation (SNP) | VAF 50/604 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.439); called by muse, mutect2
- NEUROD4 | c.650T>C p.M217T | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- NFE2L2 | c.402+4A>T | Splice Region (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- NLRP12 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.038); called by muse, mutect2
- NRXN1 | c.3774G>T p.E1258D | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- NSMAF | c.2030C>G p.S677C | Missense Mutation (SNP) | VAF 17/337 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.132); called by muse, mutect2
- OBSCN | c.14368G>T p.D4790Y | Missense Mutation (SNP) | VAF 20/265 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2
- OR10A2 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 28/522 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- OR14A2 | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2
- OR1C1 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.206); called by muse, mutect2
- OR2G2 | c.346G>T p.V116F | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- OR9Q2 | c.753C>G p.F251L | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- OTX1 | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2
- PADI2 | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, varscan2
- PHOX2B | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PI4KA | c.3403G>T p.D1135Y | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2
- PKHD1 | c.10946C>A p.A3649D | Missense Mutation (SNP) | VAF 24/363 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- PLA1A | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 18/610 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEKHM2 | c.1891A>T p.T631S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PNLIPRP1 | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.199); called by muse, mutect2
- PPM1H | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP1CB | c.534C>A p.D178E | Missense Mutation (SNP) | VAF 39/459 reads (8%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.009); called by muse, mutect2
- PRR14L | c.5417C>G p.T1806S | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.164); called by muse, mutect2
- PTGER4 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 43/819 reads (5%) | called by muse, mutect2
- RAD21L1 | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 23/356 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- RNF144B | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RYR1 | c.13831G>A p.G4611S | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.46); PolyPhen probably damaging (1); called by muse, mutect2
- SECISBP2 | c.1603-1G>T p.X535_splice | Splice Site (SNP) | VAF 55/495 reads (11%) | called by muse, mutect2, varscan2
- SH2D4B | c.997A>G p.S333G | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2
- SHROOM4 | c.1169A>T p.E390V | Missense Mutation (SNP) | VAF 22/285 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2
- SLC2A2 | c.1523G>T p.R508M | Missense Mutation (SNP) | VAF 106/869 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC49A4 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 44/1222 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC6A3 | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 25/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SORL1 | c.3781G>T p.D1261Y | Missense Mutation (SNP) | VAF 23/500 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- STAB2 | c.4319G>T p.C1440F | Missense Mutation (SNP) | VAF 41/390 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- SULT1C2 | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 42/596 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYTL5 | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 37/426 reads (9%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.566); called by muse, mutect2
- SZT2 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- TAB3 | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- TENM2 | c.4726G>T p.V1576F (on ENST00000518659 / NM_001122679.2; = p.V1337F on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- THSD7A | c.2455T>A p.Y819N | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); called by muse, mutect2
- TIAM2 | c.2792A>G p.Y931C | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TNN | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2
- TRAPPC2 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); called by muse, mutect2
- TRAV12-2 | c.320C>A p.T107N | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TTN | c.67942G>A p.E22648K (on ENST00000591111; = p.E15224K on NM_003319.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | PolyPhen benign (0.318); called by muse, mutect2
- TTN | c.67282G>C p.E22428Q (on ENST00000591111; = p.E15004Q on NM_003319.4) | Missense Mutation (SNP) | VAF 10/168 reads (6%) | PolyPhen possibly damaging (0.603); called by muse, mutect2
- TUBA3C | c.954G>T p.L318F | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.384); called by muse, mutect2
- UMODL1 | c.224A>C p.Y75S | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDR45 | c.545C>T p.S182L (on ENST00000376372 / NM_001029896.2; = p.S183L on NM_007075.3) | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2
- WWP1 | c.1613G>A p.G538D | Missense Mutation (SNP) | VAF 53/887 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- XCL1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- ZBTB11 | c.1489G>T p.G497C | Missense Mutation (SNP) | VAF 22/438 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.219); called by muse, mutect2
- ZFC3H1 | c.2692A>T p.R898* | Nonsense Mutation (SNP) | VAF 30/340 reads (9%) | called by muse, mutect2
- ZFHX4 | c.7872del p.L2625Cfs*20 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- ZNF155 | c.1195A>T p.S399C | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- ZNF331 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF331 | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- ZNF404 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF492 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 20/575 reads (3%) | called by muse, mutect2
- ZNF512B | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF727 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 37/438 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); called by muse, mutect2
- ABCC12 | c.1596G>T p.L532= | Silent (SNP) | VAF 11/230 reads (5%) | catalogued as rs1209422242; called by muse, mutect2
- AGBL1 | c.465C>G p.T155= | Silent (SNP) | VAF 24/404 reads (6%) | called by muse, mutect2
- ANK2 | c.6417C>A p.V2139= | Silent (SNP) | VAF 28/270 reads (10%) | called by muse, mutect2
- CACNB4 | c.465C>G p.L155= | Silent (SNP) | VAF 40/570 reads (7%) | called by muse, mutect2
- CATSPER4 | c.846G>T p.G282= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- CEBPZ | c.387A>C p.A129= | Silent (SNP) | VAF 46/370 reads (12%) | called by muse, mutect2, varscan2
- COL27A1 | c.4806G>A p.P1602= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs147409979; ClinVar: likely benign; called by mutect2, varscan2
- COL3A1 | c.564T>A p.S188= | Silent (SNP) | VAF 44/746 reads (6%) | called by muse, mutect2
- DCAF4L2 | c.447T>C p.L149= | Silent (SNP) | VAF 21/225 reads (9%) | called by muse, mutect2
- DCLK1 | c.2166G>A p.S722= (on ENST00000360631 / NM_001330072.2; = p.S415= on NM_001195416.2) | Silent (SNP) | VAF 36/472 reads (8%) | catalogued as rs1372942208; called by muse, mutect2
- FBRSL1 | c.786G>A p.L262= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, varscan2
- GALNT9 | c.111C>A p.L37= | Silent (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- GPR158 | c.3330C>A p.A1110= | Silent (SNP) | VAF 30/375 reads (8%) | called by muse, mutect2
- GSG1 | c.138G>T p.L46= (on ENST00000651961 / NM_001080555.4; = p.L33= on NM_031289.5) | Silent (SNP) | VAF 15/227 reads (7%) | called by muse, mutect2
- GTPBP3 | c.898C>T p.L300= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as rs757148398, COSV50176320; called by muse, mutect2, varscan2
- HCRTR2 | c.537C>T p.V179= | Silent (SNP) | VAF 38/929 reads (4%) | catalogued as rs1156923610; called by muse, mutect2
- HTR4 | c.195G>T p.A65= | Silent (SNP) | VAF 66/748 reads (9%) | called by muse, mutect2
- HYDIN | c.11034A>G p.Q3678= | Silent (SNP) | VAF 12/326 reads (4%) | catalogued as rs559965594; called by muse, mutect2
- LHX8 | c.906G>T p.L302= | Silent (SNP) | VAF 54/605 reads (9%) | called by muse, mutect2
- MGAT5B | c.234G>T p.L78= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- MN1 | c.840G>T p.A280= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV56561172; called by muse, varscan2
- MYOM1 | c.1272A>T p.L424= | Silent (SNP) | VAF 36/578 reads (6%) | called by muse, mutect2
- MYT1L | c.1224G>T p.R408= | Silent (SNP) | VAF 35/450 reads (8%) | called by muse, mutect2
- NEGR1 | c.690T>A p.I230= | Silent (SNP) | VAF 22/378 reads (6%) | called by muse, mutect2
- NLRP3 | c.627C>A p.P209= | Silent (SNP) | VAF 32/302 reads (11%) | catalogued as COSV60227943; called by muse, mutect2, varscan2
- NPY1R | c.909G>T p.L303= | Silent (SNP) | VAF 30/279 reads (11%) | called by muse, mutect2, varscan2
- OR14C36 | c.294G>A p.Q98= | Silent (SNP) | VAF 54/641 reads (8%) | called by muse, mutect2
- OR2L2 | c.340C>T p.L114= | Silent (SNP) | VAF 38/612 reads (6%) | called by muse, mutect2
- OR56A5 | c.468C>A p.G156= | Silent (SNP) | VAF 13/307 reads (4%) | called by muse, mutect2
- OXER1 | c.348C>T p.I116= | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- PAPPA2 | c.3969G>C p.L1323= | Silent (SNP) | VAF 44/578 reads (8%) | called by muse, mutect2
- PGK2 | c.300A>T p.V100= | Silent (SNP) | VAF 27/475 reads (6%) | called by muse, mutect2
- PWWP3A | c.762G>T p.P254= (on ENST00000627377; = p.P253= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 7/56 reads (13%) | called by mutect2, varscan2
- RXFP2 | c.747C>G p.P249= | Silent (SNP) | VAF 48/818 reads (6%) | called by muse, mutect2
- SFXN5 | c.552G>T p.L184= | Silent (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- SH3BP4 | c.1509G>T p.T503= | Silent (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- SRL | c.211C>T p.L71= | Silent (SNP) | VAF 15/132 reads (11%) | called by muse, mutect2, varscan2
- TAF2 | c.717C>A p.T239= | Silent (SNP) | VAF 28/698 reads (4%) | called by muse, mutect2
- TBC1D26 | c.459G>T p.L153= | Silent (SNP) | VAF 35/375 reads (9%) | catalogued as rs753634632; called by muse, mutect2, varscan2
- TFAP2D | c.150C>A p.T50= | Silent (SNP) | VAF 32/424 reads (8%) | catalogued as rs370679010; called by muse, mutect2
- TG | c.315G>A p.L105= | Silent (SNP) | VAF 54/748 reads (7%) | called by muse, mutect2
- THSD7B | c.1065G>T p.G355= | Silent (SNP) | VAF 38/568 reads (7%) | catalogued as COSV55688829; called by muse, mutect2
- TOPORS | c.1488A>G p.E496= | Silent (SNP) | VAF 86/994 reads (9%) | called by muse, mutect2
- TPO | c.1452G>A p.V484= | Silent (SNP) | VAF 29/231 reads (13%) | called by muse, mutect2, varscan2
- ULK4 | c.2299T>C p.L767= | Silent (SNP) | VAF 13/190 reads (7%) | called by muse, mutect2
- WDR33 | c.1977G>A p.Q659= | Silent (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- ZDHHC23 | c.303C>G p.V101= | Silent (SNP) | VAF 20/530 reads (4%) | called by muse, mutect2
- ZMAT1 | c.1071A>G p.S357= | Silent (SNP) | VAF 26/432 reads (6%) | called by muse, mutect2
- ZNF728 | c.681C>A p.P227= | Silent (SNP) | VAF 30/600 reads (5%) | catalogued as COSV101655362; called by muse, mutect2
- ZNF729 | c.2514C>A p.A838= | Silent (SNP) | VAF 44/1096 reads (4%) | called by muse, mutect2
- BROX | c.-205C>T | 5'UTR (SNP) | VAF 16/260 reads (6%) | catalogued as rs957214749; called by muse, mutect2
- CCDC85C | c.*14510T>G | 3'UTR (SNP) | VAF 35/338 reads (10%) | called by muse, mutect2, varscan2
- CIDEA | c.38+392C>A | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100255274; called by muse, mutect2, varscan2
- CNTN4 | c.2398+43T>A | Intron (SNP) | VAF 17/144 reads (12%) | called by muse, mutect2
- COX7A2L | c.204+10G>C | Intron (SNP) | VAF 20/291 reads (7%) | catalogued as COSV52242912; called by muse, mutect2
- DEFB121 | c.-20T>A | 5'UTR (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- DUOX1 | c.1216+61G>T | Intron (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2
- FUNDC2P2 | n.277C>T | RNA (SNP) | VAF 44/409 reads (11%) | called by muse, mutect2, varscan2
- GOLGA6L7 | c.462+21G>T | Intron (SNP) | VAF 10/220 reads (5%) | catalogued as COSV101629707; called by muse, mutect2
- GVINP1 | n.2674C>T | RNA (SNP) | VAF 12/241 reads (5%) | catalogued as rs919134025; called by muse, mutect2
- IGKV1D-27 | n.158G>T | RNA (SNP) | VAF 39/718 reads (5%) | called by muse, mutect2
- LTBP4 | c.2759-14G>T | Intron (SNP) | VAF 17/151 reads (11%) | catalogued as rs750385800; called by muse, mutect2, varscan2
- MARCHF1 | c.242+616T>C | Intron (SNP) | VAF 52/763 reads (7%) | called by muse, mutect2
- NLRP7 | chr19:54947681 G>T | 5'Flank (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- NSG2 | c.*131G>T | 3'UTR (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- NUMBL | c.-7G>A | 5'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- OR52Z1 | n.398C>A | RNA (SNP) | VAF 8/165 reads (5%) | called by muse, mutect2
- OR7E5P | n.531C>G | RNA (SNP) | VAF 40/884 reads (5%) | called by muse, mutect2
- PADI1 | c.*70A>G | 3'UTR (SNP) | VAF 13/254 reads (5%) | catalogued as rs1279007056; called by muse, mutect2
- PEX5L | c.22-1520A>T | Intron (SNP) | VAF 28/444 reads (6%) | called by muse, mutect2
- PRSS40A | n.142-2281G>T | Intron (SNP) | VAF 17/355 reads (5%) | called by muse, mutect2
- RASGRF2 | c.1390+342G>A | Intron (SNP) | VAF 15/190 reads (8%) | called by muse, mutect2
- SLC2A11 | c.984+36G>C | Intron (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2
- SNORD109A | n.59C>T | RNA (SNP) | VAF 14/264 reads (5%) | catalogued as rs1348658050; called by muse, mutect2
- SNORD115-1 | n.11T>A | RNA (SNP) | VAF 25/249 reads (10%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-2222G>A | Intron (SNP) | VAF 123/697 reads (18%) | called by muse, mutect2, varscan2
- SVIL2P | n.1308G>A | RNA (SNP) | VAF 28/392 reads (7%) | called by muse, mutect2
- TRBV4-1 | c.-10C>A | 5'UTR (SNP) | VAF 33/239 reads (14%) | called by muse, mutect2, varscan2
- Unknown | chr16:27290262 C>T | IGR (SNP) | VAF 28/310 reads (9%) | called by muse, mutect2
- WASF4P | n.34C>A | RNA (SNP) | VAF 16/344 reads (5%) | called by muse, mutect2
- ZFPM2 | n.250del | RNA (DEL) | VAF 22/170 reads (13%) | called by mutect2, pindel, varscan2
- ZNF521 | c.-70G>T | 5'UTR (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- ZNF99 | c.*3374C>A | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- ZNF99 | c.*3373C>A | 3'UTR (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
